Somatic mutation profile of tumor specimen C3L-01036-01 (aliquot CPT0123440006_1) from CPTAC case C3L-01036, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.2 years (23,457 days).
Specimen C3L-01036-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71735e57-502f-490e-a4fc-d4dac0c1c8b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01036-31 (Blood Derived Normal), aliquot CPT0124820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7664eaf2-454b-4708-8fb9-52791197e5db

The open-access MAF lists 82 somatic variants for this specimen: 44 protein-altering or splice-affecting, 25 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 25, Intron 7, Nonsense Mutation 2, RNA 2, Splice Region 2, 5'Flank 2, Frame Shift Del 1, 5'UTR 1, In Frame Ins 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 47/648 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 43/320 reads (13%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGEF18 | c.2434G>A p.A812T (on ENST00000359920 / NM_001130955.2; = p.A708T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/517 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1359446974; called by muse, mutect2, varscan2
- CDC42BPG | c.2818G>A p.V940I | Missense Mutation (SNP) | VAF 45/421 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs1200159529; called by muse, mutect2, varscan2
- CFAP47 | c.7844C>T p.T2615I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.039); catalogued as rs967476751; called by muse, mutect2
- EIF4G3 | c.2624A>G p.H875R | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs570848878; called by muse, mutect2, varscan2
- FOXE1 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.113); catalogued as COSV64300253; called by muse, mutect2
- GRID1 | c.2146G>A p.G716R | Missense Mutation (SNP) | VAF 60/407 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs779959152, COSV60038671; called by muse, mutect2, varscan2
- GTF3C1 | c.5588G>A p.R1863H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs370190480; called by muse, mutect2
- HRH2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 96/728 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs781393851; called by muse, mutect2, varscan2
- JAG2 | c.2332C>T p.R778W | Missense Mutation (SNP) | VAF 66/661 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1452922654; called by muse, mutect2, varscan2
- JAK3 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 62/405 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.453); catalogued as rs201784993, COSV71686009; called by muse, mutect2, varscan2
- LAMA1 | c.3496G>A p.V1166M | Missense Mutation (SNP) | VAF 65/396 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs545607128, COSV67534155; called by muse, mutect2, varscan2
- LYST | c.11069C>T p.T3690M | Missense Mutation (SNP) | VAF 79/605 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1380931438, COSV67704269; called by muse, mutect2, varscan2
- MYO3A | c.4682G>A p.R1561Q | Missense Mutation (SNP) | VAF 63/607 reads (10%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs773690359, COSV56325431, COSV56342277; called by muse, mutect2, varscan2
- NFIC | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 43/401 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59413275; called by muse, mutect2, varscan2
- PLEKHG4B | c.2141G>A p.R714H (on ENST00000283426; = p.R1070H on NM_052909.5) | Missense Mutation (SNP) | VAF 53/352 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as rs148131393; called by muse, mutect2, varscan2
- PLEKHM1 | c.48G>A p.P16= | Splice Region (SNP) | VAF 62/601 reads (10%) | catalogued as rs1459508370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA1 | c.4369G>T p.A1457S | Missense Mutation (SNP) | VAF 85/953 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52532961; called by muse, mutect2
- PTN | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 38/300 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs777555367, COSV61964495, COSV61965937; called by muse, varscan2
- PTPRM | c.4183C>T p.R1395C | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753091710, COSV59842875; called by muse, mutect2, varscan2
- SLC18A2 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs751675923, COSV53690884; called by muse, mutect2, varscan2
- USP2 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 58/451 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs765354693; called by muse, mutect2, varscan2
- WDR86 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs914805975; called by muse, mutect2, varscan2
- AZIN1 | c.500_502dup p.N167dup | In Frame Ins (INS) | VAF 38/404 reads (9%) | called by mutect2, pindel
- BEND4 | c.847T>C p.S283P | Missense Mutation (SNP) | VAF 55/433 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C19orf47 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 66/467 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ENPEP | c.2840G>A p.R947K | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOSL2 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 111/825 reads (13%) | called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- KDM4E | c.595A>G p.N199D | Missense Mutation (SNP) | VAF 77/754 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LONP2 | c.218T>A p.L73Q | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by mutect2, varscan2
- MARK2 | c.1613_1614dup p.H539Cfs*78 (on ENST00000402010 / NM_001039469.2; = p.H505Cfs*78 on NM_017490.4) | Frame Shift Ins (INS) | VAF 42/421 reads (10%) | called by mutect2, pindel
- MYO9B | c.3241C>T p.Q1081* | Nonsense Mutation (SNP) | VAF 92/749 reads (12%) | called by muse, mutect2, varscan2
- NF1 | c.7752T>G p.I2584M (on ENST00000358273 / NM_001042492.3; = p.I2563M on NM_000267.3) | Missense Mutation (SNP) | VAF 62/580 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- NTF3 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2
- PDYN | c.-19-1G>A | Splice Site (SNP) | VAF 15/269 reads (6%) | called by muse, mutect2
- PDZRN4 | c.1100G>T p.S367I (on ENST00000402685 / NM_001164595.2; = p.S109I on NM_013377.4) | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.981); called by muse, mutect2
- SAMD9 | c.3461A>T p.D1154V | Missense Mutation (SNP) | VAF 83/800 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SP3 | c.2260_2275del p.S754Kfs*76 | Frame Shift Del (DEL) | VAF 30/293 reads (10%) | called by mutect2, pindel
- STAG2 | c.3140C>A p.S1047Y | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLE4 | c.1319C>A p.T440K | Missense Mutation (SNP) | VAF 38/379 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF567 | c.788G>T p.C263F (on ENST00000536254 / NM_001322913.1; = p.C232F on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/332 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ZNF695 | c.1274A>G p.Q425R | Missense Mutation (SNP) | VAF 17/409 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.038); called by muse, mutect2
- AC138647.1 | c.522G>A p.T174= | Silent (SNP) | VAF 8/148 reads (5%) | catalogued as rs928558505; called by muse, mutect2
- ADAMTS14 | c.924C>T p.L308= | Silent (SNP) | VAF 59/518 reads (11%) | catalogued as rs143037838, COSV100941847; called by muse, mutect2, varscan2
- BSN | c.2436C>T p.H812= | Silent (SNP) | VAF 37/271 reads (14%) | catalogued as rs754219572, COSV56521041; called by muse, mutect2, varscan2
- C4orf19 | c.603T>C p.H201= | Silent (SNP) | VAF 44/394 reads (11%) | called by muse, mutect2, varscan2
- CALU | c.255C>T p.D85= | Silent (SNP) | VAF 27/168 reads (16%) | catalogued as rs770954063; called by muse, mutect2, varscan2
- CHRNB2 | c.879C>T p.D293= | Silent (SNP) | VAF 64/468 reads (14%) | catalogued as COSV100872621; called by muse, mutect2, varscan2
- COL5A1 | c.1239C>T p.D413= | Silent (SNP) | VAF 60/559 reads (11%) | catalogued as rs775974461; called by muse, mutect2, varscan2
- FNIP1 | c.2055A>T p.G685= | Silent (SNP) | VAF 46/382 reads (12%) | called by muse, mutect2, varscan2
- GPX6 | c.654C>T p.F218= | Silent (SNP) | VAF 41/325 reads (13%) | catalogued as COSV62657244; called by muse, mutect2, varscan2
- HOXD1 | c.462C>T p.Y154= | Silent (SNP) | VAF 57/571 reads (10%) | catalogued as COSV100514176; called by muse, mutect2, varscan2
- IFIH1 | c.2166A>C p.I722= | Silent (SNP) | VAF 61/529 reads (12%) | called by muse, mutect2, varscan2
- INTS5 | c.2691G>A p.T897= | Silent (SNP) | VAF 27/189 reads (14%) | catalogued as rs1201907983; called by muse, mutect2, varscan2
- LOXHD1 | c.2841C>T p.D947= | Silent (SNP) | VAF 128/958 reads (13%) | catalogued as rs761010290; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRK2 | c.4323C>T p.R1441= | Silent (SNP) | VAF 72/712 reads (10%) | catalogued as rs112998035; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMRN2 | c.2049C>T p.D683= | Silent (SNP) | VAF 21/159 reads (13%) | called by muse, mutect2, varscan2
- NCAN | c.2751G>A p.P917= | Silent (SNP) | VAF 69/568 reads (12%) | catalogued as rs764591928, COSV53060225; called by muse, mutect2, varscan2
- NEUROD4 | c.936C>A p.S312= | Silent (SNP) | VAF 28/222 reads (13%) | catalogued as COSV54472848; called by muse, mutect2, varscan2
- PCDHB5 | c.1587C>T p.R529= | Silent (SNP) | VAF 179/1211 reads (15%) | catalogued as rs781920885, COSV50660007; called by muse, mutect2, varscan2
- PDZRN3 | c.1866C>T p.N622= | Silent (SNP) | VAF 86/794 reads (11%) | catalogued as rs553747931, COSV55190281; called by muse, mutect2, varscan2
- PRAMEF18 | c.714C>T p.F238= | Silent (SNP) | VAF 58/1086 reads (5%) | catalogued as rs752123611; called by muse, mutect2
- SALL1 | c.2895G>A p.V965= | Silent (SNP) | VAF 118/879 reads (13%) | catalogued as rs1351117612; called by muse, mutect2, varscan2
- SLC25A51 | c.783G>C p.R261= | Silent (SNP) | VAF 44/620 reads (7%) | called by muse, mutect2
- TBX3 | c.1329G>A p.S443= (on ENST00000257566 / NM_016569.4; = p.S423= on NM_005996.4) | Silent (SNP) | VAF 33/275 reads (12%) | catalogued as rs773964538, COSV57472125; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM132A | c.1698G>A p.T566= (on ENST00000453848 / NM_178031.3; = p.T567= on NM_017870.4) | Silent (SNP) | VAF 65/607 reads (11%) | catalogued as rs565546668; called by muse, mutect2, varscan2
- ZNF227 | c.1920C>T p.G640= | Silent (SNP) | VAF 25/234 reads (11%) | called by muse, mutect2, varscan2
- AC073648.1 | n.135C>T | RNA (SNP) | VAF 38/275 reads (14%) | catalogued as rs751580610; called by muse, mutect2, varscan2
- ADH1A | c.347+36G>A | Intron (SNP) | VAF 58/450 reads (13%) | catalogued as rs1238180863; called by muse, mutect2, varscan2
- CCDC136 | c.-132G>T | 5'UTR (SNP) | VAF 30/196 reads (15%) | called by muse, varscan2
- CLUL1 | chr18:613258 C>A | 5'Flank (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- EPB41L3 | chr18:5630430 G>A | 5'Flank (SNP) | VAF 111/1081 reads (10%) | called by muse, mutect2
- FBN2 | c.3344-48A>G | Intron (SNP) | VAF 14/369 reads (4%) | called by muse, mutect2
- GRIA4 | c.487+44689A>G | Intron (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- PIK3IP1 | c.308-23G>A | Intron (SNP) | VAF 19/153 reads (12%) | catalogued as rs1303048534; called by muse, mutect2, varscan2
- RAB28 | c.391+831T>C | Intron (SNP) | VAF 16/188 reads (9%) | catalogued as rs1560140982; called by muse, mutect2
- REEP6 | c.517+161C>T | Intron (SNP) | VAF 50/362 reads (14%) | catalogued as rs747519860; called by muse, varscan2
- TNFAIP2 | c.*609G>A | 3'UTR (SNP) | VAF 44/262 reads (17%) | catalogued as rs1164521202; called by muse, mutect2, varscan2
- TTC3P1 | n.5684A>T | RNA (SNP) | VAF 71/339 reads (21%) | called by muse, mutect2, varscan2
- ZEB2 | c.-69-14T>A | Intron (SNP) | VAF 19/586 reads (3%) | called by muse, mutect2
